HCMI case HCM-EXPT-1061-C50 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Ductal and Lobular Neoplasms; Primary site: Breast.
https://portal.gdc.cancer.gov/cases/770a4929-73e0-4420-bdc4-94355f5a46bc

Demographics
Sex at birth: female; Year of birth: 1944.

Diagnoses (1)
1. Infiltrating duct carcinoma, NOS: ICD-O-3 morphology code: 8500/3; ICD-10 code: C50.9; Tissue or organ of origin: Breast, NOS; Site of resection or biopsy: Breast, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 73.4 years (26,819 days); Prior treatment: No.
   Recorded as not given: neoadjuvant treatment (type not reported).

Biospecimens (1 sample; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample HCM-EXPT-1061-C50-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
  Slide HCM-EXPT-1061-C50-01A-01-S2-HE: Section location: Bottom; Percent tumor cells: 64; Percent tumor nuclei: 73; Percent normal cells: 23; Percent necrosis: 2; Percent stromal cells: 11; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide HCM-EXPT-1061-C50-01A-01-S1-HE: Section location: Top; Percent tumor cells: 60; Percent tumor nuclei: 77; Percent normal cells: 18; Percent necrosis: 1; Percent stromal cells: 21; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
